Somatic mutation profile of tumor specimen TARGET-30-PAPKWN-01A (aliquot TARGET-30-PAPKWN-01A-01W) from TARGET case TARGET-30-PAPKWN, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 1.9 years (710 days).
Specimen TARGET-30-PAPKWN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65d35d4c-9d52-4f87-b519-ffec363b7914.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAPKWN-10A (Blood Derived Normal), aliquot TARGET-30-PAPKWN-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9e56c35-11df-4dd7-971a-8c23e27030f1

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 8, Silent 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CMYA5 | c.11173G>A p.V3725I | Missense Mutation (SNP) | VAF 48/251 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs202239777, COSV71406477; called by muse, mutect2, varscan2
- ESD | c.800C>T p.T267I | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV66340414; called by muse, mutect2, varscan2
- GDF5 | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as COSV65501858; called by muse, mutect2
- MYCBP2 | c.13577G>A p.R4526Q (on ENST00000357337; = p.R4564Q on NM_015057.5) | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs542069034, COSV100630983, COSV62022737; called by muse, mutect2, varscan2
- SIRPB1 | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 37/182 reads (20%) | catalogued as COSV53539128, COSV53539741; called by muse, mutect2, varscan2
- ZBTB38 | c.1532C>T p.T511M | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368195627; called by muse, mutect2, varscan2
- MUC16 | c.19601G>T p.R6534M | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.183); called by muse, mutect2
- PYHIN1 | c.1469C>A p.A490E | Missense Mutation (SNP) | VAF 16/230 reads (7%) | PolyPhen probably damaging (0.972); called by muse, mutect2
- SLC22A9 | c.1598del p.N533Mfs*18 | Frame Shift Del (DEL) | VAF 25/127 reads (20%) | called by mutect2, pindel, varscan2
- TRAPPC2 | c.226G>T p.V76F | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.274); called by muse, mutect2
- OR2AE1 | c.609C>T p.S203= | Silent (SNP) | VAF 85/262 reads (32%) | catalogued as rs1255390555, COSV60390401; called by muse, mutect2, varscan2
- PDIA5 | c.138G>A p.R46= | Silent (SNP) | VAF 54/246 reads (22%) | catalogued as COSV60249767; called by muse, mutect2, varscan2
